Gene-level copy-number profile of tumor specimen TCGA-AR-A2LN-01A from TCGA case TCGA-AR-A2LN, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 65.7 years (23,992 days).
Specimen TCGA-AR-A2LN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.e0e62b44-bcb1-4776-843d-a9493b115324.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AR-A2LN-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/dd14d1e9-9c29-42ba-902d-0db2657c0c47

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 2: 2,584; copy number 4: 54,041; copy number 6: 2,678; copy number 7: 3; copy number 8: 10; copy number 9: 9; copy number 10: 111; copy number 11: 64; copy number 14: 30; copy number 15: 30; copy number 23: 156; copy number 25: 1; copy number 26: 96; copy number 30: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AR-A2LN-01A-21D-A18N-01): tumor purity 0.42, ploidy 2.06, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:87,944,885–87,950,819, 1 gene: RPS4XP15.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 499 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:37,575,587–37,576,384, 1 gene, copy number 25: ZNF970P.
- chr12:64,759,484–80,068,757, 251 genes, copy number 23–26 (within-gene range 2–26) (broad region; genes not listed).
- chr12:80,102,899–80,103,333, 1 gene, copy number 26: AC078817.1.
- chr12:85,781,892–85,836,409, 2 genes, copy number 30: AC137768.1, RASSF9.
- chr12:87,041,916–87,820,918, 9 genes, copy number 9: AC079597.1, RPL23AP68, AC079598.4, CYCSP30, AC079598.2, MKRN9P, LINC02258, AC079598.1, AC079598.3.
- chr12:89,588,049–90,889,917, 14 genes, copy number 10 (within-gene range 2–10): ATP2B1, ATP2B1-AS1, AC009522.1, RNA5SP365, MRPL2P1, RNU6-148P, BRWD1P2, LINC02399, AC126178.1, LINC02392, LINC02822, AC084365.1, AC112481.2, AC112481.1.
- chr12:92,702,843–96,485,442, 94 genes, copy number 11–14 (broad region; genes not listed).
- chr12:97,150,081–97,995,448, 22 genes, copy number 10: AC007656.3, AC007656.4, LINC02409, RMST, MIR1251, AC007351.2, AC007351.3, AC007351.4, AC007351.1, AC018659.4, AC018659.3, AC018659.1, AC018659.7, AC018659.5, AC018659.8, MIR135A2, AC018659.6, AC018659.2, PAFAH1B2P2, RNU6-36P, MIR4495, MIR4303.
- chr12:99,647,753–100,628,288, 20 genes, copy number 10: FAM71C, AC078916.1, RPS4XP1, AC126474.1, UHRF1BP1L, AC126474.2, AC010203.2, GOLGA2P5, RN7SL176P, AC010203.1, MIR1827, ACTR6, DEPDC4, Y_RNA, SCYL2, SLC17A8, NR1H4, AC010200.1, GAS2L3, PIGAP1.
- chr18:42,743,227–47,102,243, 55 genes, copy number 10 (within-gene range 2–10): RIT2, AC100779.1, SYT4, AC022743.1, AC083760.1, RNA5SP455, AC110014.1, LINC01478, KRT8P5, MLECP1, SETBP1-DT, SETBP1, AC021766.1, MIR4319, AC105074.1, AC090376.1, SLC14A2, SLC14A2-AS1, AC021517.1, AC021517.3, AC091151.2, AC091151.7, AC091151.1, AC023421.1, AC023421.2, SLC14A1, AC087685.1, SIGLEC15, EPG5, PSTPIP2, RN7SKP26, AC012569.1, RNY4P37, ATP5F1A, HAUS1, RNU6-1278P, C18orf25, RNF165, AC015959.1, AC018931.1, LOXHD1, ST8SIA5, AC090311.1, AC090241.2, AC090241.3, PIAS2, AC090241.1, AC090373.1, KATNAL2, ELOA3D, ELOA3C, ELOA3B, ELOA3, ELOA2, AC012254.5.
- chr18:62,650,308–64,992,828, 30 genes, copy number 15: RN7SL705P, PHLPP1, RNU6-142P, BCL2, AC022726.1, AC022726.2, KDSR, AC036176.1, VPS4B, AC036176.2, SERPINB5, AC036176.3, ATP5MC1P6, SERPINB12, SERPINB13, SERPINB4, SERPINB11, SERPINB3, SERPINB7, SERPINB2, SERPINB10, HMSD, AC009802.1, SERPINB8, LINC01924, RPL12P39, LINC00305, LINC01538, AC027506.1, AC090348.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
